Somatic mutation profile of tumor specimen TCGA-61-1727-01A (aliquot TCGA-61-1727-01A-01W-0639-09) from TCGA case TCGA-61-1727, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 74.5 years (27,203 days).
Specimen TCGA-61-1727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5451e5fa-80ba-4298-821f-e3d84d2beeed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1727-11A (Solid Tissue Normal), aliquot TCGA-61-1727-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e84b40fc-d354-4031-a217-37cbdbfcb32f

The open-access MAF lists 142 somatic variants for this specimen: 117 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 23, Splice Site 5, Nonsense Mutation 3, In Frame Del 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53143043; called by muse, varscan2
- ACTR8 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99213913; called by muse, mutect2
- ADAMTS12 | c.3231C>G p.S1077R | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV61255799, COSV61256233; called by muse, mutect2, varscan2
- ADGRG4 | c.8501T>G p.M2834R | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54949907; called by muse, mutect2, varscan2
- AGL | c.2001+1G>C p.X667_splice | Splice Site (SNP) | VAF 15/117 reads (13%) | catalogued as COSV54048274; called by muse, mutect2, varscan2
- AHCYL1 | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63208214; called by muse, varscan2
- AIM2 | c.395A>T p.K132M | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63698271; called by muse, mutect2, varscan2
- ANKRD16 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99510568; called by muse, mutect2
- ANKRD30A | c.817C>G p.P273A (on ENST00000611781; = p.P217A on NM_052997.2) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as COSV100654553; called by muse, mutect2
- ASTN1 | c.3802C>T p.L1268F | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV62491136; called by muse, mutect2, varscan2
- B4GALNT1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57541318; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 28/190 reads (15%) | catalogued as rs745882580; called by mutect2, varscan2
- CACNG3 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV50064129; called by muse, mutect2, varscan2
- CCAR1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV99771485; called by muse, mutect2
- CD109 | c.3340A>G p.R1114G | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs748708308, COSV54653401, COSV99754807; called by muse, mutect2, varscan2
- CHRNA3 | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100468752; called by muse, mutect2
- CNGA1 | c.2014A>G p.S672G | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100652370; called by muse, mutect2
- COL11A1 | c.5249T>G p.I1750S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV62173277; called by muse, mutect2, varscan2
- COL1A2 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51953070; called by muse, mutect2, varscan2
- COL4A5 | c.4061G>C p.G1354A | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60356295; called by muse, mutect2, varscan2
- CTNNBL1 | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63743695; called by muse, mutect2, varscan2
- CUL1 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57386801, COSV57389269; called by muse, mutect2, varscan2
- CXXC1 | c.1457G>T p.C486F | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53273193; called by muse, mutect2, varscan2
- DDX60 | c.3115C>G p.Q1039E | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV67095126; called by muse, mutect2, varscan2
- DGKK | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV65706404; called by muse, mutect2, varscan2
- DIS3L | c.1458T>A p.D486E (on ENST00000319212 / NM_001143688.3; = p.D403E on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59911032; called by muse, mutect2, varscan2
- DMXL1 | c.4737C>G p.H1579Q | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60705004; called by muse, mutect2, varscan2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG3 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs761041733, COSV57124237; called by muse, mutect2, varscan2
- DSG3 | c.1898-1G>C p.X633_splice | Splice Site (SNP) | VAF 35/141 reads (25%) | catalogued as COSV57124246, COSV57125790; called by muse, mutect2, varscan2
- DYNC1H1 | c.10098G>C p.K3366N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV64134453; called by muse, mutect2, varscan2
- EGFL6 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV63632864; called by muse, mutect2, varscan2
- EIF4G3 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV51674155; called by muse, mutect2, varscan2
- EPB41L3 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV59444847; called by muse, mutect2, varscan2
- EPS8L3 | c.1399C>G p.R467G (on ENST00000361965 / NM_133181.4; = p.R437G on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV62608767, COSV62609288; called by muse, mutect2, varscan2
- FAM13B | c.2689G>C p.A897P | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50364265; called by muse, mutect2, varscan2
- FBH1 | c.2786T>G p.L929R (on ENST00000362091 / NM_178150.3; = p.L980R on NM_032807.4) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62981604; called by muse, mutect2, varscan2
- FCRL2 | c.1189A>T p.M397L | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63832576; called by muse, mutect2, varscan2
- FIGN | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60764860; called by muse, mutect2, varscan2
- FLG | c.1491C>G p.H497Q | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs116222149, COSV64236654; called by muse, mutect2
- FSHR | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.993); catalogued as COSV58617696, COSV58630882; called by muse, mutect2, varscan2
- GOPC | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50000547; called by muse, mutect2, varscan2
- GRIK4 | c.2177T>A p.M726K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV70799869; called by muse, mutect2, varscan2
- GRIPAP1 | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99502181; called by muse, mutect2
- HIVEP3 | c.2677C>G p.L893V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56009837; called by muse, mutect2, varscan2
- HMCN1 | c.12559A>C p.I4187L | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV54878074; called by muse, mutect2, varscan2
- IGLV10-54 | c.239A>C p.E80A | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV66504769; called by muse, mutect2, varscan2
- ITGA3 | c.1678A>C p.N560H | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as COSV50306095; called by muse, mutect2, varscan2
- ITGB6 | c.1206C>G p.H402Q | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51790900; called by muse, mutect2, varscan2
- KAT6A | c.4261G>C p.D1421H | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55902781; called by muse, mutect2, varscan2
- KRT27 | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 207/324 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.533); catalogued as COSV56970793; called by muse, mutect2, varscan2
- LAMB1 | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV55961680; called by muse, mutect2, varscan2
- MAP3K15 | c.2377T>A p.F793I | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58826074; called by muse, mutect2, varscan2
- MAP3K9 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67119902; called by muse, mutect2, varscan2
- MBNL3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63730204; called by muse, mutect2, varscan2
- MCF2L2 | c.2134T>G p.Y712D | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61049310; called by muse, mutect2, varscan2
- MYO5B | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 64/536 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs767154177, COSV53211544; called by muse, mutect2, varscan2
- NAA25 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV55702111; called by muse, mutect2, varscan2
- NDNF | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as COSV65632593; called by muse, mutect2, varscan2
- NEXMIF | c.4231G>C p.G1411R | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs769601623, COSV50021990; called by muse, mutect2, varscan2
- NLRP10 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV60778718, COSV60779844; called by muse, mutect2, varscan2
- NLRP4 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756893701, COSV56708028; called by muse, mutect2, varscan2
- NTRK2 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as COSV52854294; called by muse, mutect2, varscan2
- OR11A1 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65820694; called by muse, mutect2, varscan2
- OR3A3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs780218861, COSV52166816; called by muse, mutect2, varscan2
- OR5V1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs867076795, COSV65826389; called by muse, mutect2, varscan2
- PCDH10 | c.2865G>A p.M955I | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52087718; called by muse, mutect2, varscan2
- PCDHGB2 | c.657C>G p.D219E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV53900506; called by muse, mutect2, varscan2
- PCDHGB3 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as rs79773129, COSV53900520; called by muse, mutect2, varscan2
- PLCB1 | c.1236G>C p.E412D | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62038760; called by muse, mutect2, varscan2
- PRKAR2A | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | catalogued as COSV55550707; called by muse, mutect2, varscan2
- PRKCG | c.1764G>A p.G588= | Splice Region (SNP) | VAF 19/55 reads (35%) | catalogued as COSV54723968, COSV54732137; called by muse, mutect2, varscan2
- RAPH1 | c.2877G>T p.K959N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV99864669; called by muse, mutect2
- RBAK-RBAKDN | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV101208288; called by muse, mutect2
- RNGTT | c.1258A>C p.T420P | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.294); catalogued as COSV55646229; called by muse, mutect2, varscan2
- RP1 | c.1573C>G p.Q525E | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55110282; called by muse, mutect2, varscan2
- RPA4 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs1264114955, COSV61260669; called by muse, mutect2, varscan2
- RYR2 | c.3908G>A p.R1303H | Missense Mutation (SNP) | VAF 64/357 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs766670579, COSV63663015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51801639; called by muse, mutect2, varscan2
- SCO1 | c.390C>G p.H130Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1205857807, COSV55134917; called by muse, mutect2, varscan2
- SERPINA10 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV100004096; called by muse, mutect2
- SIPA1L2 | c.3737A>C p.D1246A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV99479898; called by muse, mutect2
- SMARCA2 | c.3726G>C p.M1242I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.838); catalogued as COSV100571598; called by muse, mutect2
- SNCB | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59434692; called by muse, mutect2, varscan2
- SRRM2 | c.3313G>T p.V1105F | Missense Mutation (SNP) | VAF 227/515 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV57068348; called by muse, mutect2, varscan2
- SRSF9 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV99986750; called by muse, mutect2
- STAG1 | c.1122C>A p.F374L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV52601828; called by muse, mutect2, varscan2
- SV2B | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV57703749; called by muse, mutect2, varscan2
- SV2B | c.1324T>C p.F442L | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs781583501, COSV57698517; called by muse, mutect2, varscan2
- SZT2 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65167247; called by muse, mutect2, varscan2
- TEX13A | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782191180, COSV61143256; called by muse, varscan2
- THSD7B | c.3776C>A p.T1259K (on ENST00000272643; = p.T1257K on NM_001316349.2) | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV55655443, COSV55710483; called by muse, mutect2, varscan2
- TRPA1 | c.3161T>C p.L1054P | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV51555587; called by muse, mutect2, varscan2
- UBR5 | c.4991A>G p.D1664G | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV55280256; called by muse, mutect2, varscan2
- USP48 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1326384905, COSV57607276; called by muse, mutect2, varscan2
- USP9X | c.266T>G p.L89W | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61066153; called by muse, mutect2, varscan2
- VMA21 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV57755943; called by muse, mutect2, varscan2
- WDR53 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV60283581; called by muse, mutect2, varscan2
- ZDHHC23 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV57628720; called by muse, mutect2, varscan2
- ZMIZ1 | c.23T>G p.I8S | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV100566635; called by muse, mutect2
- ZNF121 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV57551078; called by muse, mutect2, varscan2
- ZNF326 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV100438326; called by muse, mutect2
- ZNF491 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV60056690; called by muse, mutect2, varscan2
- ZNF799 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.756); catalogued as COSV70121956; called by mutect2, varscan2
- ZNRF4 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99706772; called by muse, mutect2
- ZSCAN5A | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54223977; called by muse, mutect2, varscan2
- ATM | c.5750_5762+8del p.X1917_splice | Splice Site (DEL) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- BIRC6 | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CTPS2 | c.338-23_339del p.X113_splice | Splice Site (DEL) | VAF 137/480 reads (29%) | called by mutect2, pindel, varscan2
- GOT1 | c.172_190del p.E58Tfs*4 | Frame Shift Del (DEL) | VAF 46/217 reads (21%) | called by mutect2, pindel, varscan2
- LPA | c.3720_3734del p.N1241_C1245del | In Frame Del (DEL) | VAF 17/155 reads (11%) | called by mutect2, pindel
- MOAP1 | c.447_463del p.L150Cfs*8 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- NLRP1 | c.1760_1798del p.S587_A599del | In Frame Del (DEL) | VAF 37/210 reads (18%) | called by mutect2, pindel
- PPP6R3 | c.2165_2192+6del p.X722_splice (on ENST00000393800 / NM_001352375.2; = p.X642_splice on NM_018312.5) | Splice Site (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel
- ROCK1 | c.1274_1303del p.Q425_K434del | In Frame Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- TPBG | c.897C>A p.D299E | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2
- ATP6V0D2 | c.711A>G p.R237= | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as COSV53413151; called by muse, mutect2, varscan2
- CNR2 | c.225C>T p.S75= | Silent (SNP) | VAF 52/82 reads (63%) | catalogued as COSV65692229; called by muse, mutect2, varscan2
- CRISPLD1 | c.1326C>A p.S442= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV51544418, COSV51553537; called by muse, mutect2, varscan2
- DGKI | c.1329C>A p.S443= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99937705; called by muse, mutect2
- DYNC2H1 | c.10869C>T p.S3623= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV62086454; called by muse, mutect2, varscan2
- ESRP2 | c.1173G>C p.L391= (on ENST00000565858 / NM_001365264.1; = p.L381= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52172000; called by muse, mutect2, varscan2
- FAM47C | c.753C>A p.P251= | Silent (SNP) | VAF 85/290 reads (29%) | catalogued as COSV63723740; called by muse, mutect2, varscan2
- GCNA | c.858C>T p.D286= | Silent (SNP) | VAF 72/328 reads (22%) | catalogued as rs1279377486, COSV65465881, COSV65466139; called by muse, mutect2, varscan2
- IFNGR1 | c.975G>A p.P325= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs376124136; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRIQ1 | c.258A>G p.G86= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV67812641; called by muse, mutect2, varscan2
- MUC7 | c.171G>A p.P57= | Silent (SNP) | VAF 81/535 reads (15%) | catalogued as rs758265177, COSV59217070; called by muse, mutect2, varscan2
- NCKAP1 | c.837A>G p.A279= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100720590; called by muse, mutect2
- NR3C2 | c.2727G>A p.K909= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs768593437, COSV100679187, COSV60985472; called by muse, mutect2, varscan2
- ORM1 | c.384C>T p.Y128= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as rs1126712, COSV99407717; called by muse, mutect2
- P4HA3 | c.663G>A p.E221= | Silent (SNP) | VAF 45/243 reads (19%) | catalogued as rs1308670716, COSV59040820; called by muse, mutect2, varscan2
- PIK3C2B | c.3726T>C p.Y1242= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as COSV65809105; called by muse, mutect2, varscan2
- PLXNA4 | c.5187T>A p.I1729= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV58105695; called by muse, mutect2, varscan2
- PRSS27 | c.675C>T p.C225= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100069749; called by muse, mutect2
- SLC4A2 | c.2919A>T p.P973= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52539136; called by muse, mutect2, varscan2
- SLC9B1 | c.390A>G p.L130= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as COSV56467174; called by muse, mutect2, varscan2
- SNAP91 | c.2457T>A p.P819= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV52115241; called by muse, mutect2, varscan2
- TPR | c.6690C>T p.T2230= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV66599484; called by muse, mutect2, varscan2
- TRPC3 | c.678C>T p.D226= (on ENST00000379645 / NM_001366479.2; = p.D153= on NM_003305.2) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1399391147, COSV53372093; called by muse, mutect2, varscan2
- DEPDC5 | c.*713A>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99836774; called by muse, mutect2
- NOP56 | c.209-181C>G | Intron (SNP) | VAF 23/88 reads (26%) | catalogued as COSV61388804; called by muse, mutect2, varscan2
